CCDI case PBBJJS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1f38b834-d77a-4b2e-b328-5e894d9af340

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 18.2 years (6,638 days).

Biospecimens (3 samples)
- Sample 0DB2AP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB2AU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB2BA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
